Somatic mutation profile of tumor specimen TCGA-D1-A17T-01A (aliquot TCGA-D1-A17T-01A-11D-A12J-09) from TCGA case TCGA-D1-A17T, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G2; Age at diagnosis: 67.5 years (24,652 days).
Specimen TCGA-D1-A17T-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 13df6193-87a5-49a5-9082-522a27f5d632.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D1-A17T-10A (Blood Derived Normal), aliquot TCGA-D1-A17T-10A-01D-A12J-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/45a9c754-170d-4471-8f2b-ad1ba1dab15c

The open-access MAF lists 77 somatic variants for this specimen: 58 protein-altering or splice-affecting, 17 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 17, Frame Shift Del 5, Nonsense Mutation 4, Splice Region 3, Intron 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHI1 | c.910dup p.T304Nfs*6 | Frame Shift Ins (INS) | VAF 96/252 reads (38%) | catalogued as rs753874898; ClinVar: pathogenic; called by mutect2, varscan2
- CTNNB1 | c.110C>G p.S37C | Missense Mutation (SNP) | VAF 33/140 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- FGFR2 | c.755C>G p.S252W | Missense Mutation (SNP) | VAF 58/174 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs79184941, CM950458, CM970526, COSV60638319; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- KMT2B | c.521del p.P174Qfs*20 | Frame Shift Del (DEL) | VAF 8/24 reads (33%) | catalogued as rs763183959; ClinVar: pathogenic; called by mutect2, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 54/128 reads (42%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.2702G>T p.C901F | Missense Mutation (SNP) | VAF 151/348 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55881149; called by muse, mutect2, varscan2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 141/499 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCB4 | c.2701G>A p.E901K | Missense Mutation (SNP) | VAF 115/253 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.857); catalogued as COSV55934686, COSV55936859; called by muse, mutect2, varscan2
- ACCSL | c.397C>T p.R133C | Missense Mutation (SNP) | VAF 49/93 reads (53%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs376261378; called by muse, mutect2, varscan2
- ACTN4 | c.193C>T p.R65W | Missense Mutation (SNP) | VAF 56/129 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53145555; called by muse, mutect2, varscan2
- ADGRV1 | c.5419G>C p.E1807Q | Missense Mutation (SNP) | VAF 29/149 reads (19%) | SIFT tolerated (0.2); PolyPhen probably damaging (1); catalogued as COSV67984280; called by muse, mutect2, varscan2
- AFF1 | c.883C>T p.R295W | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57119370; called by muse, mutect2, varscan2
- AKAP13 | c.2510del p.T837Sfs*4 | Frame Shift Del (DEL) | VAF 12/40 reads (30%) | catalogued as COSV63455387; called by mutect2, pindel, varscan2
- ARHGAP30 | c.1891G>A p.G631R | Missense Mutation (SNP) | VAF 137/302 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.34); catalogued as COSV100920343, COSV63516186; called by muse, mutect2, varscan2
- ARID1A | c.2179_2188del p.R727Vfs*12 | Frame Shift Del (DEL) | VAF 48/119 reads (40%) | catalogued as COSV61376658; called by mutect2, pindel, varscan2
- ARID1A | c.6806C>A p.S2269* | Nonsense Mutation (SNP) | VAF 39/84 reads (46%) | catalogued as COSV100252068, COSV61371645, COSV61375637; called by muse, mutect2, varscan2
- ARID5B | c.1489del p.I497* | Frame Shift Del (DEL) | VAF 105/216 reads (49%) | catalogued as rs201178069; called by mutect2, pindel, varscan2
- ATM | c.68G>A p.R23Q | Missense Mutation (SNP) | VAF 96/253 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587779858, COSV53740048; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BMP2K | c.202G>C p.V68L | Missense Mutation (SNP) | VAF 87/256 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs770167074, COSV58594734, COSV58601109; called by muse, mutect2, varscan2
- CD1C | c.60C>T p.D20= | Splice Region (SNP) | VAF 109/264 reads (41%) | catalogued as rs539975387, COSV63806226; called by muse, mutect2, varscan2
- CEACAM20 | c.1595C>T p.P532L | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.664); catalogued as COSV57601577; called by muse, mutect2
- CEP78 | c.1573G>A p.E525K (on ENST00000424347 / NM_001349840.2; = p.E526K on NM_032171.3) | Missense Mutation (SNP) | VAF 52/341 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781419520, COSV52847078; called by muse, mutect2, varscan2
- COL11A1 | c.5389T>A p.F1797I | Missense Mutation (SNP) | VAF 59/256 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62182062; called by muse, mutect2, varscan2
- FAT3 | c.9249C>T p.G3083= | Splice Region (SNP) | VAF 101/227 reads (44%) | catalogued as rs758619349, COSV53095028; called by muse, mutect2, varscan2
- FGGY | c.554G>A p.R185Q | Missense Mutation (SNP) | VAF 28/298 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774970699, COSV58025386, COSV58047101; called by muse, mutect2, varscan2
- GALNT14 | c.1456G>A p.A486T | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.053); catalogued as rs149431826; called by muse, mutect2, varscan2
- GDF7 | c.1232C>T p.P411L | Missense Mutation (SNP) | VAF 47/110 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55347575; called by muse, mutect2, varscan2
- GNAT2 | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 75/174 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as rs759770362, COSV63554859; called by muse, mutect2, varscan2
- GTPBP4 | c.1108G>A p.D370N | Missense Mutation (SNP) | VAF 89/286 reads (31%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs995568946, COSV62550754; called by muse, mutect2, varscan2
- KCNJ9 | c.397C>T p.P133S | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as COSV63631710; called by muse, mutect2, varscan2
- KIF21B | c.4459G>A p.E1487K (on ENST00000422435 / NM_001252100.2; = p.E1474K on NM_017596.4) | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs1477823118, COSV59756972; called by muse, mutect2, varscan2
- LGALS4 | c.898C>T p.R300C | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs777741497, COSV57042901; called by muse, mutect2, varscan2
- MBD5 | c.421C>T p.R141W | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs757105717, COSV68695810, COSV68696813; called by muse, mutect2, varscan2
- MOCS3 | c.1012G>T p.V338F | Missense Mutation (SNP) | VAF 10/190 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV54866322; called by muse, mutect2
- MRGPRX1 | c.235C>T p.R79C | Missense Mutation (SNP) | VAF 69/152 reads (45%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.849); catalogued as rs923586872, COSV57107051; called by muse, mutect2, varscan2
- NCAM2 | c.1054G>A p.G352S | Missense Mutation (SNP) | VAF 21/198 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.81); catalogued as rs776715131, COSV53053970; called by muse, mutect2, varscan2
- NCKAP5L | c.1553G>T p.G518V | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV100258814, COSV60129299; called by muse, varscan2
- NCR2 | c.428G>A p.R143H | Missense Mutation (SNP) | VAF 50/105 reads (48%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as rs142832518; called by muse, mutect2, varscan2
- NID2 | c.2546C>T p.A849V | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as rs1468289403, COSV53495868; called by muse, mutect2, varscan2
- NLRP11 | c.265C>T p.R89* | Nonsense Mutation (SNP) | VAF 83/177 reads (47%) | catalogued as rs751156777, COSV64085872; called by muse, mutect2, varscan2
- NLRP3 | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 74/151 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as rs533920557, COSV60221235, COSV60223557; called by muse, mutect2, varscan2
- NUP210 | c.892C>T p.R298W | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1398683960, COSV54405843; called by muse, mutect2, varscan2
- OPN1LW | c.744G>A p.A248= | Splice Region (SNP) | VAF 122/415 reads (29%) | catalogued as rs139583770, COSV64049361; called by muse, mutect2, varscan2
- OSBPL5 | c.2050C>T p.R684W | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs746630605, COSV55140887; called by muse, mutect2, varscan2
- PCDHA7 | c.1535C>T p.A512V | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); catalogued as rs1554135453, COSV65343748; called by muse, mutect2, varscan2
- PFKFB1 | c.1296C>A p.C432* | Nonsense Mutation (SNP) | VAF 60/174 reads (34%) | catalogued as COSV51500927; called by muse, mutect2, varscan2
- PPP2R2D | c.118G>A p.V40I | Missense Mutation (SNP) | VAF 265/476 reads (56%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.999); catalogued as rs1554896165, COSV71863036; called by muse, mutect2, varscan2
- PTEN | c.955_958del p.T319* | Frame Shift Del (DEL) | VAF 114/236 reads (48%) | catalogued as rs146650273; called by pindel, varscan2
- RYR2 | c.7624G>A p.A2542T | Missense Mutation (SNP) | VAF 143/365 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.301); catalogued as rs373602064, COSV63682696; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SAMD4A | c.1024G>A p.A342T | Missense Mutation (SNP) | VAF 98/214 reads (46%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.448); catalogued as rs778052233, COSV51880189; called by muse, mutect2, varscan2
- SCAI | c.1681C>T p.R561* (on ENST00000336505 / NM_001144877.3; = p.R584* on NM_173690.5) | Nonsense Mutation (SNP) | VAF 15/553 reads (3%) | catalogued as COSV60612441; called by muse, mutect2
- SIN3A | c.932T>A p.V311D | Missense Mutation (SNP) | VAF 22/316 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64582737; called by muse, mutect2
- STK38 | c.407C>G p.A136G | Missense Mutation (SNP) | VAF 47/193 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57708737; called by muse, mutect2, varscan2
- TEAD2 | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 31/332 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs751545411, COSV55562252; called by muse, mutect2
- TNR | c.3779A>G p.Y1260C | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1449296576, COSV54883225; called by muse, mutect2, varscan2
- ZFHX4 | c.6469G>A p.E2157K | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.464); catalogued as COSV50732602; called by muse, mutect2, varscan2
- ZIC4 | c.768C>A p.H256Q | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV67171515; called by muse, mutect2
- ZXDA | c.982C>T p.R328W | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62387919; called by muse, mutect2, varscan2
- BEST3 | c.468C>T p.H156= | Silent (SNP) | VAF 52/112 reads (46%) | catalogued as rs370248128; called by muse, mutect2, varscan2
- CPSF1 | c.3624G>A p.T1208= | Silent (SNP) | VAF 26/44 reads (59%) | catalogued as rs782030221, COSV58232443; called by muse, mutect2, varscan2
- CSNK1A1L | c.627C>T p.Y209= | Silent (SNP) | VAF 161/395 reads (41%) | catalogued as rs1213625867, COSV65789620; called by muse, mutect2, varscan2
- CSPP1 | c.24C>G p.A8= | Silent (SNP) | VAF 24/72 reads (33%) | catalogued as rs988655476, COSV51583853; called by muse, mutect2, varscan2
- DBH | c.228C>G p.L76= | Silent (SNP) | VAF 30/73 reads (41%) | catalogued as rs781202782, COSV55039698, COSV55040601, COSV99708149; called by muse, mutect2, varscan2
- DCAF12L1 | c.672G>A p.P224= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as rs770105970, COSV64421435; called by muse, mutect2, varscan2
- FAM47A | c.825C>T p.D275= | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as COSV60494645; called by muse, mutect2, varscan2
- GTF2E1 | c.498A>T p.S166= | Silent (SNP) | VAF 98/216 reads (45%) | catalogued as COSV52204119; called by muse, mutect2, varscan2
- INTS10 | c.1200A>G p.K400= | Silent (SNP) | VAF 31/233 reads (13%) | catalogued as COSV67604097; called by muse, mutect2, varscan2
- JAGN1 | c.12A>G p.R4= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as rs377365266; called by muse, mutect2, varscan2
- KCNK9 | c.351C>A p.G117= | Silent (SNP) | VAF 37/111 reads (33%) | catalogued as COSV57280973; called by muse, mutect2, varscan2
- KLRF1 | c.207A>G p.K69= | Silent (SNP) | VAF 126/296 reads (43%) | catalogued as COSV54380777; called by muse, mutect2, varscan2
- LAMC3 | c.3687G>A p.L1229= | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as COSV62654054; called by muse, mutect2, varscan2
- MROH5 | c.2094C>T p.D698= | Silent (SNP) | VAF 67/168 reads (40%) | catalogued as COSV71301377; called by muse, mutect2
- PLXNA4 | c.4638C>T p.P1546= | Silent (SNP) | VAF 144/305 reads (47%) | catalogued as COSV58121963; called by muse, mutect2, varscan2
- RIMBP3 | c.3669G>A p.P1223= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as rs1230445702; called by mutect2, varscan2
- SSTR4 | c.828C>T p.Y276= | Silent (SNP) | VAF 243/571 reads (43%) | catalogued as rs755279669, COSV54796877; called by muse, mutect2, varscan2
- GABRA3 | c.-26-27651G>A | Intron (SNP) | VAF 72/164 reads (44%) | catalogued as rs372715021, COSV64798190, COSV64806029; called by muse, mutect2, varscan2
- TANGO2 | c.-39-3614G>T | Intron (SNP) | VAF 27/71 reads (38%) | catalogued as COSV59293563; called by muse, mutect2, varscan2
